Somatic mutation profile of tumor specimen 0D9K44 from CCDI case PBBIWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,906 days).
Specimen 0D9K44: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b6494c8-faf1-4589-9a3d-746f2ce1758c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9K4A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2efeee61-9da7-4578-b8de-335d77bd381d

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 6, RNA 2, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 148/373 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- ABCF1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1048893050, COSV58228256; called by muse, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by muse, varscan2
- CATSPERB | c.1057A>T p.I353F | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs764188524, COSV56431662; called by muse, mutect2, varscan2
- DCAF8L1 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 49/692 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1252554186; called by muse, mutect2
- LARP6 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54581968; called by muse, mutect2, varscan2
- PHC2 | c.1457G>C p.R486P | Missense Mutation (SNP) | VAF 160/326 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs370173676; called by mutect2, varscan2
- PIK3AP1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 227/502 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs373505645; called by muse, varscan2
- PRSS12 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 64/520 reads (12%) | catalogued as rs146884286; called by muse, mutect2, varscan2
- PSME2 | c.262+6A>T | Splice Region (SNP) | VAF 18/466 reads (4%) | catalogued as rs1036195966; called by muse, mutect2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 50/296 reads (17%) | catalogued as rs759765382; called by mutect2, varscan2
- ZNF716 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs1554324641, COSV70783072; called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/678 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HSP90AA1 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 111/577 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- LBHD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SMARCD2 | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); called by muse, mutect2
- WDR75 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 33/504 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF716 | c.627G>T p.R209S | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by mutect2, varscan2
- ZNF726 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FMR1NB | c.141C>A p.A47= | Silent (SNP) | VAF 38/240 reads (16%) | catalogued as COSV100975503; called by mutect2, varscan2
- KRTAP4-8 | c.468C>T p.G156= | Silent (SNP) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- CTSC | c.318+6725T>G | Intron (SNP) | VAF 20/127 reads (16%) | called by muse, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, varscan2
- EMC4 | c.355+84C>T | Intron (SNP) | VAF 16/133 reads (12%) | called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 18/120 reads (15%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- MUC19 | n.9719G>T | RNA (SNP) | VAF 96/882 reads (11%) | called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 9/83 reads (11%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 32/272 reads (12%) | called by muse, varscan2
